Somatic mutation profile of tumor specimen BA2702D (aliquot aq-BA2702D) from BEATAML1.0 case 2001, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.8 years (25,127 days).
Specimen BA2702D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7f21279-294d-4224-9b32-ff96c0d544ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2213D (Solid Tissue Normal), aliquot aq-BA2213D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8636ffcd-2829-46d0-a09f-fae5122e2fc5

The open-access MAF lists 28 somatic variants for this specimen: 14 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 13, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 88/229 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- KIF21A | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770064077, COSV62766767; ClinVar: benign; called by muse, mutect2, varscan2
- PAPPA2 | c.4144G>A p.G1382R | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV100868707; called by muse, mutect2, varscan2
- PDZRN4 | c.2696G>A p.R899Q (on ENST00000402685 / NM_001164595.2; = p.R641Q on NM_013377.4) | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471240360, COSV54195797; called by muse, mutect2, varscan2
- SLC24A5 | c.8C>A p.T3K | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as COSV58319409, COSV99050379; called by muse, mutect2, varscan2
- AKAP13 | c.7876G>T p.V2626L (on ENST00000394518 / NM_007200.5; = p.V2630L on NM_006738.6) | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDC14A | c.1474A>G p.T492A | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP13-2 | c.370T>A p.S124T | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2
- NAV2 | c.2838C>G p.S946R (on ENST00000396087 / NM_001244963.2; = p.S923R on NM_145117.5) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, varscan2
- NPC1L1 | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); called by muse, mutect2
- NXF3 | c.407A>T p.E136V | Missense Mutation (SNP) | VAF 98/114 reads (86%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OGT | c.1565C>A p.A522D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.731); called by muse, mutect2
- STYXL2 | c.1723G>T p.A575S | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF716 | c.527A>T p.K176M | Missense Mutation (SNP) | VAF 96/276 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- ALPK3 | c.3039C>A p.R1013= | Silent (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- BCL11B | c.2538C>T p.H846= (on ENST00000357195 / NM_001282237.2; = p.H775= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/132 reads (40%) | catalogued as rs746847233, COSV100595694; called by muse, mutect2, varscan2
- CEP250 | c.1545C>T p.H515= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs1305558095; called by muse, mutect2, varscan2
- CLDN8 | c.552C>T p.C184= | Silent (SNP) | VAF 103/235 reads (44%) | catalogued as rs746476394; called by muse, mutect2, varscan2
- FMO1 | c.495C>T p.A165= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV61444683; called by muse, mutect2, varscan2
- IL12RB2 | c.594C>G p.A198= | Silent (SNP) | VAF 175/425 reads (41%) | called by muse, mutect2, varscan2
- KIF1B | c.4152C>G p.T1384= (on ENST00000377086 / NM_001365952.1; = p.T1338= on NM_015074.3) | Silent (SNP) | VAF 105/247 reads (43%) | called by muse, mutect2, varscan2
- KRTAP12-2 | c.318G>C p.V106= | Silent (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2
- MGMT | c.372G>A p.S124= (on ENST00000306010; = p.S93= on NM_002412.5) | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs779649950; called by muse, mutect2, varscan2
- RYR1 | c.3351C>T p.D1117= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as rs151182947; called by muse, mutect2, varscan2
- TMEM132B | c.861T>C p.P287= | Silent (SNP) | VAF 42/112 reads (38%) | called by muse, mutect2, varscan2
- TNIK | c.3189G>T p.G1063= | Silent (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
- UBXN6 | c.666G>A p.G222= | Silent (SNP) | VAF 59/142 reads (42%) | called by muse, mutect2, varscan2
- PPP4R1L | n.1473G>T | RNA (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
